Surgical pathology report (de-identified scan), TCGA case TCGA-CN-4730, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-CN-4730-01A (Primary Tumor).

[page 1 of 6]
PATIENT HISTORY:

CHIEF COMPLAINT/ PRE-OP/ POST-OP DIAGNOSIS: Left oral cavity cancer.

PROCEDURE: DL mandibulectomy composite free flap.

SPECIFIC CLINICAL QUESTION: Not answered.

OUTSIDE TISSUE DIAGNOSIS: Not answered.

PRIOR MALIGNANCY: Not answered.

CHEMORADIATION THERAPY: Not answered.

ORGAN TRANSPLANT: Not answered.

IMMUNOSUPPRESSION: Not answered.

OTHER DISEASES: Not answered.

Dictated by: [REDACTED]

FINAL DIAGNOSIS:

PART 1: ORAL CAVITY, LEFT, BIOPSY –

INVASIVE SQUAMOUS CELL CARCINOMA, MODERATELY DIFFERENTIATED, WITH ACUTE AND CHRONIC INFLAMMATION.

PART 2: LYMPH NODES, LEFT NECK LEVEL 1A, EXCISION –

THREE BENIGN LYMPH NODES (0/3).

PART 3: FLOOR OF MOUTH AND LEFT PARTIAL MANDIBULECTOMY-

- A. SQUAMOUS CELL CARCINOMA, MODERATELY DIFFERENTIATED, 2.5 CM, INVADING THE MANDIBLE ASSOCIATED WITH ACUTE ABSCESS FORMATION (see synoptic).
- B. MARGINS OF RESECTION INCLUDING BONE ARE FREE OF TUMOR (SEE PARTS 4, 5, 6, 7, 8, 9 AND 10)
- C. METASTATIC TUMOR IDENTIFIED IN ONE LYMPH NODE (1/10), NO EXTRANODAL SPREAD IS SEEN.
- D. SALIVARY GLAND WITH NO SPECIFIC PATHOLOGIC CHANGE.
- E. NO PERINEURAL INVASION SEEN.
- F. METASTATIC SQUAMOUS CELL CARCINOMA IN 1 OF 10 ATTACHED LYMPH NODES (1/10). THE POSITIVE LYMPH NODE IS LOCATED JUST BENEATH THE MAIN TUMOR. NO EXTRANODAL SPREAD IS SEEN.
- G. PATHOLOGIC STAGE pT4aN1Mx

PART 4: FLOOR OF MOUTH, LEFT, ADDITIONAL BIOPSY –

- A. NO TUMOR SEEN.
- B. MARKED ACUTE AND CHRONIC INFLAMMATION.

PART 5: MANDIBULAR GINGIVA, MESIAL, BIOPSY –

NO TUMOR SEEN.

PART 6: FLOOR OF MOUTH, ANTERIOR, SHAVE BIOPSY –

NO TUMOR SEEN.

PART 7: TONSILLAR PILAR, ANTERIOR, SHAVE BIOPSY –

[page 2 of 6]
Pathology Report

NO TUMOR SEEN.

PART 8: GINGIVA, RETROMOLAR TRIGONE, BIOPSY –
NO TUMOR SEEN.

PART 9: DEEP MARGIN, BIOPSY –
NO TUMOR SEEN.

PART 10: SUPERFICIAL MARGIN, BIOPSY –
NO TUMOR SEEN.

PART 11: LYMPH NODES, LEFT NECK LEVELS 2 AND 3, EXCISION –
TWENTY- FOUR BENIGN LYMPH NODES (0/24).

My signature is attestation that I have personally reviewed the submitted material(s) and the final diagnosis reflects that evaluation.

GROSS DESCRIPTION:

The specimen is received in eleven parts.

Part 1 is received fresh for intraoperative consultation labeled with the patient's name, medical record number, initials and "left oral cavity". It consists of multiple fragments of white-tan, soft tissue measuring in aggregate 2.5 x 2.1 x 0.5 cm. The tissue is entirely submitted in one cassette labeled 1A.

Part 2 is received fresh labeled with the patient's name, medical record number, initials and "left neck level 1A". It consists of a single fragment of yellow-tan, fibroadipose tissue measuring 4.6 x 2.3 x 1.2 cm. Two possible lymph nodes are identified and measure 1.6 x 0.7 x 0.3 cm and 1.5 x 1.0 x 0.8 cm. Tissue is representatively submitted as follows:

2A – one bisected lymph node

2B – one lymph node

2C – representative section of soft tissue.

Part 3 is received fresh labeled with the patient's name, medical record number, initials and "left composite floor of mouth". It consists of a 7.0 x 5.8 x 3.6 cm mass of tissue that includes a 5.0 x 1.6 x 0.7 cm segment of mandible and associated soft tissue that further include a 5.6 x 3.6 x 3.2 cm yellow-tan lobulated submandibular gland and a 3.0 x 4.0 cm area of tan-pink mucosa. No teeth are present. There is a tan-white, lobulated, firm mass measuring 2.5 x 1.3 x 2.3 cm located on the floor of the mouth involving the lingual surface of the mandible. Six possible lymph nodes are identified in the adjacent soft tissue and range in size from 0.5 x 0.5 x 0.5 cm to 1.5 x 1.4 x 1.0 cm.

Additional studies:

Tumor is frozen and banked.

Digital photographs are taken.

Representative sections are submitted as follows:

3A – lateral bone margin following decalcification

3B – medial bone margin following decalcification

3C – 3D – complete cross-section of tumor with bone, bisected, following decalcification

[page 3 of 6]
Pathology Report

3E – 3F – representative sections of tumor removed from the periosteum
3G – representative sections of submandibular gland
3H – gingival mucosa above the tumor
3I – one lymph node, bisected
3J – four possible lymph nodes
3K – one lymph node, bisected.

Part 4 is received fresh labeled with the patient's name, medical record number, initials [REDACTED] and "additional left floor of mouth". It consists of a 3.6 x 1.5 x 1.0 cm fragment of soft tissue including a 3.6 x 0.8 cm portion of tan-pink mucosa. The tissue is bisected and entirely submitted in two cassettes labeled 4A and 4B.

Part 5 is received fresh for intraoperative consultation labeled with the patient's name, medical record number, initials [REDACTED] and "mesial mandibular gingiva". It consists of multiple fragments of tan-pink, soft tissue measuring in aggregate 2.0 x 2.0 x 0.5 cm. The tissue is entirely submitted in one cassette labeled 5A.

Part 6 is received fresh for intraoperative consultation labeled with the patient's name, medical record number, initials [REDACTED] and "floor of mouth, clip anterior". The specimen consists of a 3.8 x 0.5 x 0.3 cm fragment of yellow-tan, soft tissue. The area of the clip is inked in blue. The tissue is entirely submitted in one cassette labeled 6A.

Part 7 is received fresh for intraoperative consultation labeled with the patient's name, medical record number, initials [REDACTED] and "anterior tonsillar pillar." It consists of a 1.8 x 0.3 x 0.2 cm fragment of red-tan, soft tissue. It is entirely submitted in one cassette labeled 7A.

Part 8 is received fresh for intraoperative consultation labeled with the patient's name, medical record number, initials [REDACTED] and "left retromolar trigone gingiva". It consists of a 2.5 x 1.0 x 0.6 cm fragment of red-tan, soft tissue. It is entirely submitted in one cassette labeled 8A.

Part 9 is received fresh for intraoperative consultation labeled with the patient's name, medical record number, initials [REDACTED] and "deep margin". It consists of multiple fragments of yellow-tan and brown, soft tissue, measuring in aggregate 2.3 x 1.6 x 0.3 cm. It is entirely submitted in one cassette labeled 9A.

Part 10 is received fresh labeled with the patient's name, medical record number, initials [REDACTED] and "superficial margin". It consists of multiple fragments of yellow-tan, soft tissue, measuring in aggregate 1.1 x 1.4 x 0.4 cm. The tissue is entirely submitted in one cassette labeled 10A.

Part 11 is received fresh labeled with the patient's name, medical record number, initials [REDACTED] and "left neck levels 2 and 3". In level 2, numerous possible lymph nodes are identified and range in size from 0.4 x 0.3 x 0.3 cm to 3.0 x 1.4 x 1.0 cm. Five possible lymph nodes are identified in level 3 and range in size from 1.0 x 0.5 x 0.4 cm to 1.6 x 0.7 x 0.7 cm. Representative sections are submitted as follows:

11A – three lymph nodes, level 2
11B – one lymph node, bisected, level 2
11C – multiple lymph nodes, level 2
11D – multiple lymph nodes, level 2
11E – multiple lymph nodes, level 2
11F – two lymph nodes, level 3
11G – multiple level lymph nodes, level 3
11H – one lymph node bisected, level 3.

INTRAOPERATIVE CONSULTATION:

1AFS: LEFT ORAL CAVITY (frozen section) –
A. MALIGNANT.

[page 4 of 6]
Pathology Report

B. SQUAMOUS CELL CARCINOMA

5AFS: MEDIAL MANDIBULAR GINGIVA, SHAVE MARGIN (frozen section) –

- A. BENIGN.
- B. NO TUMOR PRESENT.
- C. BENIGN ODONTOGENIC REST

6AFS: FLOOR OF MOUTH, SHAVE MARGIN (frozen section) –

- A. BENIGN.
- B. NO TUMOR PRESENT

7AFS: ANTERIOR TONSILLAR PILLAR, SHAVE MARGIN (frozen section) –

- A. BENIGN.
- B. NO TUMOR PRESENT

8AFS: RETROMOLAR TRIGONE GINGIVA, SHAVE MARGIN (frozen section) –

- A. BENIGN.
- B. NO TUMOR PRESENT

9AFS: DEEP MARGIN (frozen section) –

- A. BENIGN.
- B. NO TUMOR PRESENT

10AFS: SUPERFICIAL MARGIN, SHAVE (frozen section) –

- A. BENIGN.
- B. NO TUMOR PRESENT

MICROSCOPIC:

Microscopic examination substantiates the above diagnosis.
Immunohistochemical stain for p16 is negative.

The following statement applies to all Immunohistochemistry, Insitu hybridization (ISH & FISH), molecular anatomic pathology, and immunofluorescence testing:

The testing was developed and its performance characteristics determined by the Department of Pathology, as required by the CLIA regulations. The testing has not been cleared or approved for the specific use by the U.S. Food and Drug Administration, but the FDA has determined such approval is not necessary for clinical use. Tissue fixation ranges from a minimum of to a maximum of

This laboratory is certified under the Clinical Laboratory Improvement Amendments of ("CLIA") as qualified to perform high-complexity clinical testing. Pursuant to the requirements of CLIA, ASR's used in this laboratory have been established and verified for accuracy and precision. Additional information about this type of test is available upon request.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY UPPER AERODIGESTIVE TRACT AND SALIVARY GLAND TUMORS

SPECIMEN TYPE:

Resection: Left Mandibulectomy

TUMOR SITE:

Oral Cavity

TUMOR SIZE:

Greatest dimension: 2.5 cm

Additional dimensions: 2.3X1.5 cm

HISTOLOGIC TYPE:

Squamous cell carcinoma, conventional

HISTOLOGIC GRADE:

G2

PATHOLOGIC STAGING (pTNM):

pT4a

pN1

[page 5 of 6]
Pathology Report

Number of regional lymph nodes examined: 37
Number of regional lymph nodes involved: 1
Extra-capsular extension of nodal tumor: Absent
pMX

MARGINS: Margins uninvolved by tumor
VENOUS/LYMPHATIC (LARGE/SMALL VESSEL) INVASION (V/L): Absent
PERINEURAL INVASION: Absent
ADDITIONAL PATHOLOGIC FINDINGS: None identified

HISTO TISSUE SUMMARY/SLIDES REVIEWED:

Part 1: Left Oral Cavity

Taken: [REDACTED]
Stain/cnt Block
H&E x 1 A
H&E x 1 A

Part 2: Left-Neck Level 1A

Taken: [REDACTED]
Stain/cnt Block
H&E x 1 A
H&E x 1 B
H&E x 1 C

Part 3: Left Composite Floor of Mouth

Taken: [REDACTED]
Stain/cnt Block
H&E x 1 A
H&E x 1 B
H&E x 1 C
RHHE Lev ___ x 1 D
RHHE Lev ___ x 1 D
RHHE Lev ___ x 1 D
H&E x 1 D
ANEG x 1 E
RHHE Lev ___ x 1 E
RHHE Lev ___ x 1 E
RHHE Lev ___ x 1 E
H&E x 1 E
P16 x 1 E
H&E x 1 F
H&E x 1 G
H&E x 1 H
H&E x 1 I
H&E x 1 J
H&E x 1 K

Part 4: Additional Left Floor of Mouth

Taken: [REDACTED]

[page 6 of 6]
Pathology Report

Stain/cnt Block
H&E x 1 A
H&E x 1 B

Part 5: Mesial Mandibular Gingiva

Taken: [REDACTED]
Stain/cnt Block
H&E x 1 A

Part 6: Floor of Mouth, Clin Anterior

Taken: [REDACTED]
Stain/cnt Block
H&E x 1 A

Part 7: Anterior Tonsillar Pillar

Taken: [REDACTED]
Stain/cnt Block
H&E x 1 A

Part 8: Retromolar Trigone Gingiva

Taken: [REDACTED]
Stain/cnt Block
H&E x 1 A

Part 9: Deep Margin

Taken: [REDACTED]
Stain/cnt Block
H&E x 1 A

Part 10: Superficial Margin

Taken: [REDACTED]
Stain/cnt Block
H&E x 1 A

Part 11: Left Neck Level 2 and 3

Taken: [REDACTED]
Stain/cnt Block
H&E x 1 A
H&E x 1 B
H&E x 1 C
H&E x 1 D
H&E x 1 E
H&E x 1 F
H&E x 1 G
H&E x 1 H

ICD-9 Diagnosis Codes: {None Entered}

Source: NCI Genomic Data Commons file 9aa9e2b8-21d1-4af4-84cb-0b3021bb0d1b (TCGA-CN-4730.6151C384-1778-4105-A016-E93084B1BACD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).